Somatic mutation profile of tumor specimen TCGA-AA-3870-01A (aliquot TCGA-AA-3870-01A-01W-0995-10) from TCGA case TCGA-AA-3870, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage IV; Age at diagnosis: 71.4 years (26,086 days).
Specimen TCGA-AA-3870-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e8c4419a-0e3d-4933-b7ad-151761237c42.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3870-10A (Blood Derived Normal), aliquot TCGA-AA-3870-10A-01W-0995-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c6b67466-36d3-4ff5-8659-0587b79ece1e

The open-access MAF lists 130 somatic variants for this specimen: 99 protein-altering or splice-affecting, 28 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 88, Silent 28, Nonsense Mutation 6, Frame Shift Ins 3, Splice Region 1, 3'UTR 1, RNA 1, Frame Shift Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.2626C>T p.R876* | Nonsense Mutation (SNP) | VAF 15/52 reads (29%) | hotspot (GDC flag); catalogued as rs121913333, CM942020, COSV57320538; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 21/27 reads (78%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABHD16A | c.1174C>T p.P392S | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65452413; called by muse, mutect2, varscan2
- ACTL8 | c.491G>A p.R164H | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as rs924872941, COSV64862530; called by muse, mutect2, varscan2
- ADAM17 | c.787C>T p.R263W | Missense Mutation (SNP) | VAF 21/774 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs865879773, COSV60397978; called by muse, mutect2
- ADAMTS5 | c.277G>A p.A93T | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.271); catalogued as COSV99537475; called by muse, mutect2, varscan2
- ADGRE3 | c.877G>A p.V293M | Missense Mutation (SNP) | VAF 49/157 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.042); catalogued as rs375117467; called by muse, mutect2, varscan2
- ATP6V1C2 | c.878A>G p.K293R | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.03); catalogued as rs763712608, COSV55364264; called by muse, mutect2, varscan2
- C12orf42 | c.829G>A p.A277T | Missense Mutation (SNP) | VAF 63/102 reads (62%) | SIFT tolerated (0.55); PolyPhen benign (0.117); catalogued as rs778318030, COSV59380119; called by muse, mutect2, varscan2
- C2orf69 | c.356G>A p.R119H | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs767688764, COSV60666206, COSV60667094; called by muse, mutect2, varscan2
- CACNA1E | c.1151G>A p.R384H | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs370964593; called by muse, varscan2
- CAD | c.365G>A p.R122Q | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV53028772; called by muse, mutect2, varscan2
- CADM1 | c.935G>A p.R312H | Missense Mutation (SNP) | VAF 176/540 reads (33%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.479); catalogued as rs1158887836, COSV59006265; called by muse, mutect2, varscan2
- CIR1 | c.1216C>T p.R406W | Missense Mutation (SNP) | VAF 91/262 reads (35%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs762930010, COSV59597591; called by muse, mutect2, varscan2
- COL5A2 | c.1793G>A p.R598H | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs529317104, COSV66408340; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CSMD3 | c.4694G>T p.R1565I (on ENST00000297405 / NM_001363185.1; = p.R1461I on NM_052900.3) | Missense Mutation (SNP) | VAF 21/516 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as COSV52143383, COSV99831411; called by muse, mutect2
- CTNNA2 | c.1264C>A p.R422S | Missense Mutation (SNP) | VAF 73/206 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.154); catalogued as COSV58154482; called by muse, mutect2, varscan2
- DCLK1 | c.2092C>T p.R698* (on ENST00000360631 / NM_001330072.2; = p.S722= on NM_004734.5) | Nonsense Mutation (SNP) | VAF 26/178 reads (15%) | catalogued as COSV55201777; called by mutect2, varscan2
- DDI1 | c.596G>A p.R199H | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV56376983, COSV56381452; called by muse, mutect2, varscan2
- DNAH1 | c.10804G>A p.D3602N | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.414); catalogued as rs377385985; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH10 | c.7915C>T p.R2639C (on ENST00000409039; = p.R2578C on NM_207437.3) | Missense Mutation (SNP) | VAF 182/252 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs774602539, COSV69005161; called by muse, mutect2, varscan2
- DNAH5 | c.6050G>A p.R2017Q | Missense Mutation (SNP) | VAF 56/164 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs775577387, COSV54240271; called by muse, mutect2, varscan2
- ERBB4 | c.621T>A p.T207= | Splice Region (SNP) | VAF 43/140 reads (31%) | catalogued as COSV53576567; called by muse, mutect2, varscan2
- FAM135B | c.3466C>T p.R1156W | Missense Mutation (SNP) | VAF 82/485 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1321133355, COSV52758375; called by muse, mutect2, varscan2
- FANCI | c.1514C>A p.P505H | Missense Mutation (SNP) | VAF 65/226 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773105092, COSV55533463; called by muse, mutect2, varscan2
- FGD2 | c.515G>A p.R172H | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs750711356, COSV51462243, COSV51463385; called by muse, mutect2, varscan2
- FLG | c.5980C>A p.H1994N | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as COSV64247295; called by muse, mutect2, varscan2
- GHR | c.473C>A p.T158N | Missense Mutation (SNP) | VAF 45/144 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as COSV50126060; called by muse, mutect2, varscan2
- GNRHR | c.160G>T p.A54S | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV56934640; called by muse, mutect2, varscan2
- HERC1 | c.10973G>C p.G3658A | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.076); catalogued as rs764828868; called by muse, mutect2, varscan2
- HOMER3 | c.232G>T p.G78W | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55356120, COSV55358567; called by muse, mutect2, varscan2
- HTR3E | c.1171C>A p.Q391K (on ENST00000415389 / NM_001256613.1; = p.Q406K on NM_182589.2) | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58948549; called by muse, mutect2, varscan2
- ITGAM | c.1477G>A p.V493M | Missense Mutation (SNP) | VAF 97/186 reads (52%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.506); catalogued as rs757551647, COSV54940309; called by muse, mutect2, varscan2
- KIF9 | c.1573G>A p.V525I | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs776004585; called by muse, mutect2, varscan2
- KIRREL1 | c.1318C>T p.R440C | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764090370, COSV63288957; called by muse, mutect2, varscan2
- KRTAP26-1 | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.44); PolyPhen benign (0.053); catalogued as rs146155445, COSV62128788; called by muse, mutect2, varscan2
- LRP1B | c.7153G>A p.G2385R | Missense Mutation (SNP) | VAF 77/265 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.618); catalogued as rs764483142, COSV67191275; called by muse, mutect2, varscan2
- MAMLD1 | c.1708C>T p.L570F | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as COSV53379865; called by muse, mutect2, varscan2
- MAPK1 | c.154G>T p.A52S | Missense Mutation (SNP) | VAF 60/168 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53188923; called by muse, mutect2, varscan2
- MELTF | c.1283C>T p.A428V | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs371452660; called by muse, mutect2, varscan2
- NDUFAF2 | c.128G>A p.G43E | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56943107; called by muse, mutect2, varscan2
- NUP205 | c.3664C>T p.R1222W | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.417); catalogued as rs202152654; called by muse, mutect2, varscan2
- OR51F2 | c.295T>C p.C99R | Missense Mutation (SNP) | VAF 208/855 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs866310871, COSV59065871; called by muse, mutect2, varscan2
- OR5B17 | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 40/135 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.155); catalogued as rs142474037; called by muse, mutect2, varscan2
- PCDHB5 | c.190G>A p.A64T | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.792); catalogued as rs139218724; called by muse, mutect2, varscan2
- PCDHGA5 | c.866C>T p.S289L | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.031); catalogued as rs1462774144, COSV53907131; called by muse, mutect2, varscan2
- PPM1K | c.146G>A p.R49Q | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.788); catalogued as rs753095031, COSV55797566; called by muse, mutect2, varscan2
- PPP4R3A | c.2495A>T p.D832V (on ENST00000554943 / NM_001366432.1; = p.D819V on NM_001284280.1) | Missense Mutation (SNP) | VAF 199/626 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.055); catalogued as COSV61506235; called by muse, mutect2, varscan2
- PPP4R4 | c.631C>T p.R211* | Nonsense Mutation (SNP) | VAF 157/471 reads (33%) | catalogued as rs565522571, COSV58557505; called by muse, mutect2, varscan2
- RPL31 | c.281A>T p.E94V | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.588); catalogued as COSV51822899; called by muse, mutect2, varscan2
- RPS6KA2 | c.982C>T p.R328W | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.251); catalogued as rs755486763, COSV55827813; called by muse, mutect2, varscan2
- SCML4 | c.581G>A p.R194Q | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.053); catalogued as rs555376188, COSV64635458; called by muse, mutect2
- SDK1 | c.562G>A p.A188T | Missense Mutation (SNP) | VAF 78/192 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.918); catalogued as rs774307438, COSV67357841; called by muse, mutect2, varscan2
- SGCG | c.346C>T p.R116C | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.071); catalogued as rs191040430, COSV54556779; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SGPP2 | c.241G>A p.V81M | Missense Mutation (SNP) | VAF 220/513 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs138702204, COSV58330549; called by muse, mutect2, varscan2
- SIGLEC6 | c.751G>A p.A251T | Missense Mutation (SNP) | VAF 72/309 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201148057, COSV58431851; called by muse, mutect2, varscan2
- SLAIN2 | c.1094G>A p.R365Q | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs750212863, COSV104386181, COSV51911266; called by muse, mutect2, varscan2
- SLC6A17 | c.413G>A p.R138H | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.52); PolyPhen benign (0.117); catalogued as rs779115935; called by muse, mutect2, varscan2
- SP140L | c.754A>G p.M252V | Missense Mutation (SNP) | VAF 49/174 reads (28%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs1194619636; called by muse, mutect2, varscan2
- SYT4 | c.486A>T p.E162D | Missense Mutation (SNP) | VAF 106/245 reads (43%) | SIFT tolerated (0.91); PolyPhen benign (0.311); catalogued as COSV54903551; called by muse, mutect2, varscan2
- TIGIT | c.304G>A p.D102N | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs146935299; called by muse, mutect2, varscan2
- TNFRSF10A | c.969G>T p.L323F | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.643); catalogued as COSV55326859, COSV55326879; called by muse, mutect2, varscan2
- TSPAN15 | c.704C>T p.A235V | Missense Mutation (SNP) | VAF 33/55 reads (60%) | SIFT tolerated (0.42); PolyPhen benign (0.343); catalogued as COSV64783936; called by muse, mutect2, varscan2
- ADAM11 | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (0.38); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- AL136295.1 | c.2399C>T p.S800F | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); called by muse, varscan2
- AMER1 | c.1101_1107dup p.E370Rfs*10 | Frame Shift Ins (INS) | VAF 24/42 reads (57%) | called by mutect2, varscan2
- ATP2A2 | c.901G>A p.A301T | Missense Mutation (SNP) | VAF 4/82 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2
- ATP2B2 | c.1387dup p.M463Nfs*15 (on ENST00000352432; = p.M429Nfs*15 on NM_001683.5) | Frame Shift Ins (INS) | VAF 16/35 reads (46%) | called by mutect2, varscan2
- BICRA | c.142G>A p.G48S | Missense Mutation (SNP) | VAF 52/159 reads (33%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- CALCRL | c.65C>A p.A22E | Missense Mutation (SNP) | VAF 125/456 reads (27%) | SIFT tolerated (0.44); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CD1E | c.398C>T p.A133V | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CNTLN | c.3389del p.K1130Rfs*14 | Frame Shift Del (DEL) | VAF 32/132 reads (24%) | called by mutect2, varscan2
- COL14A1 | c.4674G>T p.K1558N | Missense Mutation (SNP) | VAF 96/182 reads (53%) | SIFT tolerated (0.12); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- COL23A1 | c.488G>A p.G163E | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH11 | c.7490A>T p.E2497V | Missense Mutation (SNP) | VAF 40/194 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- FADS2 | c.416A>T p.H139L | Missense Mutation (SNP) | VAF 45/116 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- GPR149 | c.1744dup p.I582Nfs*6 | Frame Shift Ins (INS) | VAF 42/152 reads (28%) | called by mutect2, varscan2
- MARCO | c.875G>A p.G292D | Missense Mutation (SNP) | VAF 21/218 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MUC16 | c.6743C>A p.P2248H | Missense Mutation (SNP) | VAF 31/356 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- NLRP5 | c.2481G>T p.Q827H | Missense Mutation (SNP) | VAF 37/127 reads (29%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- NOTCH3 | c.5717G>A p.G1906D | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR11H6 | c.620G>T p.C207F | Missense Mutation (SNP) | VAF 87/280 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR2M4 | c.191G>A p.S64N | Missense Mutation (SNP) | VAF 54/334 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- PEG3 | c.4660G>A p.G1554S | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.005); called by mutect2, varscan2
- PSG5 | c.418T>C p.F140L | Missense Mutation (SNP) | VAF 66/812 reads (8%) | SIFT tolerated (0.58); PolyPhen benign (0.015); called by muse, mutect2
- PYHIN1 | c.1074A>T p.K358N | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.023); called by muse, mutect2
- RYK | c.1031T>A p.F344Y (on ENST00000620660 / NM_001005861.2; = p.F341Y on NM_002958.4) | Missense Mutation (SNP) | VAF 28/606 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.433); called by muse, mutect2
- RYR2 | c.5795T>C p.F1932S | Missense Mutation (SNP) | VAF 49/112 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- SETX | c.6671G>T p.G2224V | Missense Mutation (SNP) | VAF 40/183 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SGCE | c.1254G>A p.W418* (on ENST00000647096; = p.W382* on NM_003919.3) | Nonsense Mutation (SNP) | VAF 32/289 reads (11%) | called by muse, mutect2, varscan2
- SND1 | c.2599A>G p.K867E | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.393); called by muse, mutect2
- SRGAP3 | c.1420G>A p.E474K | Missense Mutation (SNP) | VAF 42/253 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.037); called by muse, varscan2
- SYDE2 | c.2691A>C p.L897F | Missense Mutation (SNP) | VAF 83/364 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- SYNE2 | c.7597G>T p.E2533* | Nonsense Mutation (SNP) | VAF 26/232 reads (11%) | called by muse, mutect2, varscan2
- TRPM3 | c.3601C>A p.Q1201K (on ENST00000357533 / NM_001366142.2; = p.Q1056K on NM_020952.6) | Missense Mutation (SNP) | VAF 59/253 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- ZC4H2 | c.223G>C p.V75L | Missense Mutation (SNP) | VAF 22/680 reads (3%) | SIFT tolerated (0.5); PolyPhen benign (0.01); called by muse, mutect2
- ZCCHC8 | c.1567C>T p.Q523* | Nonsense Mutation (SNP) | VAF 49/86 reads (57%) | called by muse, mutect2, varscan2
- ZHX3 | c.2860G>A p.E954K | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ZNF835 | c.91C>G p.Q31E | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AATF | c.678C>T p.A226= | Silent (SNP) | VAF 155/453 reads (34%) | catalogued as rs544972942; called by muse, mutect2, varscan2
- ALMS1 | c.8109G>A p.P2703= | Silent (SNP) | VAF 70/186 reads (38%) | catalogued as rs759983484, COSV52517405; called by muse, mutect2, varscan2
- AMACR | c.966C>T p.D322= | Silent (SNP) | VAF 38/103 reads (37%) | catalogued as rs906797872, COSV56874910; ClinVar: likely benign; called by muse, mutect2, varscan2
- CALD1 | c.1629C>T p.R543= (on ENST00000361675 / NM_033138.4; = p.R288= on NM_004342.7) | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as rs779036893, COSV62652806; called by muse, mutect2, varscan2
- CPA1 | c.522C>T p.I174= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as rs1554411490, COSV50573937; called by muse, mutect2, varscan2
- CPN1 | c.813C>T p.C271= | Silent (SNP) | VAF 205/347 reads (59%) | catalogued as rs149621307; called by muse, mutect2, varscan2
- DVL2 | c.795C>T p.I265= | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as rs1377473921, COSV50039021; called by muse, mutect2, varscan2
- ELP2 | c.222T>C p.P74= | Silent (SNP) | VAF 101/210 reads (48%) | catalogued as COSV60853874; called by muse, mutect2, varscan2
- GRAMD1B | c.2172C>T p.R724= | Silent (SNP) | VAF 22/59 reads (37%) | catalogued as rs1390628564, COSV59201858; called by muse, mutect2, varscan2
- HECW1 | c.69G>A p.A23= | Silent (SNP) | VAF 12/20 reads (60%) | catalogued as rs201182663, COSV67840989; called by muse, mutect2, varscan2
- HEPACAM | c.345C>T p.A115= | Silent (SNP) | VAF 54/162 reads (33%) | catalogued as rs531436968, COSV53432109; called by muse, mutect2, varscan2
- HFM1 | c.2379A>C p.T793= | Silent (SNP) | VAF 84/334 reads (25%) | catalogued as COSV54035497; called by muse, mutect2, varscan2
- ITGA6 | c.633T>C p.Y211= | Silent (SNP) | VAF 41/145 reads (28%) | catalogued as rs771847409, COSV51251751; called by muse, mutect2, varscan2
- ITSN1 | c.3993C>A p.R1331= | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as rs757375182, COSV67157537; called by muse, mutect2, varscan2
- LOXL3 | c.1290C>T p.V430= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as COSV51212323; called by muse, mutect2, varscan2
- MTF1 | c.567C>A p.I189= | Silent (SNP) | VAF 11/236 reads (5%) | catalogued as COSV65988500; called by muse, mutect2
- MYO3A | c.489A>T p.G163= | Silent (SNP) | VAF 87/346 reads (25%) | catalogued as COSV56345349; called by muse, mutect2, varscan2
- OR6C74 | c.723C>T p.S241= | Silent (SNP) | VAF 87/128 reads (68%) | catalogued as rs772190595, COSV59607130; called by muse, mutect2, varscan2
- PAN2 | c.3351G>C p.L1117= (on ENST00000425394 / NM_001127460.3; = p.L1113= on NM_014871.5) | Silent (SNP) | VAF 53/73 reads (73%) | catalogued as COSV56265045; called by muse, mutect2, varscan2
- PCDHGA2 | c.2415G>A p.T805= | Silent (SNP) | VAF 20/68 reads (29%) | catalogued as COSV54014664; called by muse, mutect2, varscan2
- RLBP1 | c.108G>A p.P36= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as rs371167491; called by muse, mutect2, varscan2
- SCN1A | c.2700C>T p.I900= (on ENST00000303395 / NM_001202435.3; = p.I889= on NM_006920.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 23/91 reads (25%) | catalogued as rs747722810, COSV57684061; called by muse, mutect2, varscan2
- SLC13A1 | c.373C>T p.L125= | Silent (SNP) | VAF 90/351 reads (26%) | catalogued as COSV52015972; called by muse, varscan2
- SYNE2 | c.565T>C p.L189= | Silent (SNP) | VAF 100/281 reads (36%) | catalogued as COSV58362382; called by muse, mutect2, varscan2
- THADA | c.4587C>T p.A1529= | Silent (SNP) | VAF 10/18 reads (56%) | catalogued as rs779355008, COSV57678939; called by muse, varscan2
- THBD | c.1005G>A p.P335= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs1478855998, COSV65703055; called by muse, mutect2
- UBN2 | c.3909A>G p.L1303= | Silent (SNP) | VAF 12/260 reads (5%) | catalogued as rs1054909918; called by muse, mutect2
- UHRF1BP1L | c.456C>A p.I152= | Silent (SNP) | VAF 120/203 reads (59%) | catalogued as COSV54441680; called by muse, mutect2, varscan2
- SDK1 | c.*3327G>A | 3'UTR (SNP) | VAF 20/76 reads (26%) | catalogued as rs371828378; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-51581T>C | Intron (SNP) | VAF 158/626 reads (25%) | catalogued as rs1208953123, COSV67448459; called by muse, mutect2, varscan2
- SSPOP | n.9194A>T | RNA (SNP) | VAF 6/17 reads (35%) | called by muse, varscan2
